Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5H5, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5H5-01A (Primary Tumor).

[page 1 of 2]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

KIDNEY, RIGHT, LAPAROSCOPIC NEPHRECTOMY:

1. Renal cell carcinoma, chromophobe type, characterized by:
- a. Tumor size: 4.5 x 4 x 2.4 cm
- b. Tumor location, upper pole of kidney
- c. Tumor grade: Grade 2 (of 4, Furman)
- d. Tumor extent: Tumor confined to kidney, abuts the overlying renal capsule but does not extend beyond
- e. Additional findings: Coagulative tumor necrosis - negative, sarcomatoid differentiation - negative
2. Margins of resection are negative for malignancy
3. Background renal parenchyma shows no significant abnormalities
4. See staging parameters

* KIDNEY STAGING PARAMETERS***

Case number: Patient name:

Final TNM: pT1bNXM0
stage: I

MACROSCOPIC

PROCEDURE

Radical nephrectomy

SPECIMEN LATERALITY

Right

TUMOR SITE

Upper pole

TUMOR SIZE

4.5 X 4 X 2.4 cm

TUMOR FOCALITY

Unifocal

MACROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

MICROSCOPIC

HISTOLOGIC TYPE

Chromophobe renal cell carcinoma

TUMOR NECROSIS

Not identified

HISTOLOGICAL GRADE

G2: Nuclei slightly irregular, approximately 15 um; nucleoli evident

MICROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

LYMPHATIC VASCULAR INVASION

Not identified

ICD-O-3

Carcinoma, renal cell
Chromophobe type 8317/3
Site R Kidney, NOS C64.9

[page 2 of 2]
MARGINS

Uninvolved by carcinoma

NON-NEOPLASTIC KIDNEY PATHOLOGY

Not identified

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1b. (Tumor more than 4 cm but not more than 7 cm in greatest dimension limited to the kidney)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1bNXM0

1 stage: I

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

year-old female patient with a 4 cm right upper pole renal mass discovered incidentally on imaging.

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right kidney

The specimen is received labeled and is designated "right kidney" and consists of a 333 gram right radical nephrectomy with associated adipose tissue measuring 12 x 16.5 x 4.5 cm. The vascular and urethral margins are removed and submitted en face. The kidney is bivalved revealing a 10 x 8 x 4 cm kidney containing a 4.5 x 4 x 2.4 cm yellow-red hemorrhagic-appearing lesion located within the upper pole. There is no tumor identified in the renal vein. The tumor appears to abut the renal capsule; however, no direct extension into the associated adipose tissue is grossly identified. Grossly this lesion comes to within 1.5 cm of the hilum. The remainder of the renal cortex has a pale tan-red appearance with an average cortical thickness of 0.6 cm. No other discrete mass lesions are identified. A portion of the tumor is taken for possible cytogenetic study and representative tissues are frozen for possible ancillary study. No lymph nodes are present within the associated adipose tissue and no adrenal gland is identified. A photo was taken of the specimen.

The specimen is sampled in 11 cassettes as follows:

1. Ureteral margin, en face
2. Vascular margins, en face
- 3-5. Representative sections of tumor
- 6-7. Tumor and adjacent normal parenchyma
- 8-9. Uninvolved renal parenchyma
- 10-11. Representative random hilar fat

Gross dictation by: [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. Dictation by [REDACTED]
transcribed by [REDACTED]

Source: NCI Genomic Data Commons file 08c76c37-5b98-42f3-8c1a-9a873d890371 (TCGA-NP-A5H5.CFC9112B-5398-4692-AD18-4055BC8EF49D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).